Surgical pathology report (de-identified scan), TCGA case TCGA-CG-4462, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Indivumed, specimen TCGA-CG-4462-01A (Primary Tumor).

■
Diagnosis:

2.: Total gastrectomy resection material with the inclusion of an extensive, focally ulcerated, poorly differentiated adenocarcinoma of the stomach (diffuse type), partially characterized by signet ring cells, with widespread infiltration of the perigastric fatty tissue, marked carcinomatous lymphangitis accompanying the tumor and twenty-five regional lymph node metastases. Subepithelial tumor infiltrates circumscribed and extending as far as both the oral and the aboral resection margin. Tumor spread in the omentum. Evidence of carcinomatous lymphangitis also in the hilar fatty tissue of the spleen.

Tumor stage: pT3 pN3 (25/25) pM1 ■ ■

Source: NCI Genomic Data Commons file 69629aa5-c82b-4ce1-bbbb-6bac420c8406 (TCGA-CG-4462.C20ADB93-ECD7-4F09-8E24-742EE7DF5F37.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).